Surgical pathology report (de-identified scan), TCGA case TCGA-EJ-7786, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site University of Pittsburgh, specimen TCGA-EJ-7786-01A (Primary Tumor).

PATIENT HISTORY:

[REDACTED] with a history of PSA value of 4.5. The patient also has a history of biopsy on [REDACTED]. This biopsy reveals: Poorly differentiated prostatic adenocarcinoma, Gleason score 4+3=7 in the right mid prostate. The patient also has a history of hydrocelectomy, gastric surgery laparoscopic, tonsillectomy, atrial fibrillation, cardiomyopathy, hypertension, and hypercholesterolemia.
PRE-OP DIAGNOSIS: Prostate cancer.
POST-OP DIAGNOSIS: Same.
PROCEDURE: Radical prostatectomy.

Collection Date: [REDACTED]

FINAL DIAGNOSIS:

PART1: LYMPH NODE, RIGHT PELVIC, EXCISION –
NO EVIDENCE OF NEOPLASIA IN THREE LYMPH NODE (0/3).

PART2: LYMPH NODE, LEFT PELVIC, EXCISION –
NO EVIDENCE OF NEOPLASIA IN TWO LYMPH NODE (0/2).

PART 3: PROSTATE AND BILATERAL SEMINAL VESICLES, RADICAL PROSTATECTOMY –

- A. PROSTATE ADENOCARCINOMA, ACINAR TYPE, GLEASON SCORE 3 + 4 = 7.
- B. THE CARCINOMA INVOLVES BOTH THE RIGHT AND LEFT LOBES AND HAS A GREATEST NODULAR DIAMETER OF 1.3 CM IN ONE HISTOLOGIC SECTION.
- C. THE CARCINOMA INVOLVES LESS THAN 5% OF THE EXAMINED PROSTATE VOLUME.
- D. THE CARCINOMA IS ORGAN CONFINED AND SHOWS NO EVIDENCE OF EXTRACAPSULAR EXTENSION.
- E. BILATERAL SEMINAL VESICLES ARE FREE OF CARCINOMA.
- F. ALL EXAMINED SURGICAL RESECTION MARGINS ARE FREE OF CARCINOMA.
- G. THERE IS FOCAL CAPSULAR INCISION IDENTIFIED BUT THE SURGICAL MARGIN IS NEGATIVE FOR TUMOR. (SLIDE 3Z, ANTERIOR LEFT APEX)
- H. NO PERINEURAL INVASION IS IDENTIFIED.
- I. NO ANGIOLYMPHATIC INVASION IS IDENTIFIED.
- J. HIGH GRADE PROSTATIC INTRAEPITHELIAL NEOPLASIA IS IDENTIFIED.
- K. PATHOLOGIC TNM STAGE: pT2c N0 MX.
- L. BACKGROUND PROSTATE TISSUE WITH NODULAR HYPERPLASIA AND CHRONIC INFLAMMATION.

CASE SYNOPSIS:**SYNOPTIC DATA - PRIMARY PROSTATE TUMORS**

CLINICAL DATA:	PSA value: 4.5
INVASIVE CA IDENTIFIED?:	Yes
TUMOR HISTOLOGY:	Adenocarcinoma NOS
PRIMARY GLEASON GRADE:	3
SECONDARY GLEASON GRADE:	4
GLEASON SUM SCORE:	7
GLEASON 4/5 PERCENTAGE:	20%

WEIGHT OF PROSTATE:	117.59gm
TUMOR SIZE:	Maximum dimension: 1.3 cm
LOBE LATERALITY:	Right and Left Lobes
PERCENT OF SPECIMEN INVOLVED BY TUMOR:	< 5% of specimen involved by invasive tumor
MULTIFOCAL DISEASE:	Yes
HIGH GRADE PIN:	Yes - multifocal
EXTRAPROSTATIC EXTENSION:	No
PERINEURAL INVASION:	No
ANGIOLYMPHATIC INVASION:	No
SEMINAL VESICLE INVASION:	No
SURGICAL MARGIN INVOLVEMENT:	All surgical margins free of tumor
RESIDUAL TUMOR:	R0
LYMPH NODES EXAMINED:	5
LYMPH NODES POSITIVE:	0
T STAGE, PATHOLOGIC:	pT2c
N STAGE, PATHOLOGIC:	pN0
M STAGE, PATHOLOGIC:	pMX
HISTOLOGIC GRADE:	G3-4, Poorly differentiated/undifferentiated

Source: NCI Genomic Data Commons file a17ab679-f7fc-491e-9ae4-218c3d2db38d (TCGA-EJ-7786.3B3AC042-2BB6-445B-A82B-EEA969F0BD33.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).